FM case AD17804 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Penis.
https://portal.gdc.cancer.gov/cases/6de71a8a-607f-450d-b500-d2b885520145

Male, 45.9 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the penis; primary biopsied or resected from the penis. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
